Somatic mutation profile of tumor specimen 1105203 (aliquot 7316UP-3301-1105203) from CPTAC case C2415597, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Temporal lobe; Tumor grade: G4.
Specimen 1105203: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f4cf7f6a-7f80-4450-9aa4-795439ba88c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105205 (Blood Derived Normal), aliquot 7316UP-3213-1105205; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02ca36cf-c839-4087-9fd3-597dff265bab

The open-access MAF lists 67 somatic variants for this specimen: 38 protein-altering or splice-affecting, 16 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 16, Intron 5, 5'UTR 3, RNA 3, Splice Region 3, Splice Site 2, 3'UTR 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 24/101 reads (24%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.993+1G>A p.X331_splice | Splice Site (SNP) | VAF 96/269 reads (36%) | hotspot (GDC flag); catalogued as rs11575997, CD002536, COSV52663229, COSV52699909, COSV52752826; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- CALML3 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 50/176 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1327202118, COSV59450316; called by muse, mutect2, varscan2
- CDC20B | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 58/279 reads (21%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs140191094, COSV57049673; called by muse, mutect2, varscan2
- CLPSL1 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 33/282 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as COSV65814701; called by muse, mutect2, varscan2
- COL18A1 | c.2926G>A p.A976T (on ENST00000359759 / NM_130444.3; = p.A741T on NM_030582.4) | Missense Mutation (SNP) | VAF 28/239 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.327); catalogued as rs777192146; called by muse, mutect2, varscan2
- DAZAP2 | c.137A>G p.Y46C | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs1489433492; called by mutect2, varscan2
- FAM47C | c.956G>A p.R319H | Missense Mutation (SNP) | VAF 83/425 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0.029); catalogued as rs142244745; called by muse, mutect2, varscan2
- KCNS1 | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 45/202 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.374); catalogued as rs1437506774; called by muse, mutect2, varscan2
- OS9 | c.1869C>G p.F623L | Missense Mutation (SNP) | VAF 16/586 reads (3%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.952); catalogued as rs945587258, COSV57731098; called by muse, mutect2
- PIEZO2 | c.4436G>A p.R1479Q | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs903681379, COSV100128741; called by muse, mutect2, varscan2
- PRDM9 | c.1843C>T p.R615W | Missense Mutation (SNP) | VAF 70/478 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57001967; called by muse, varscan2
- RUSC2 | c.3394_3396del p.I1132del | In Frame Del (DEL) | VAF 16/72 reads (22%) | catalogued as rs1170690908; called by pindel, varscan2
- SCLT1 | c.1187G>A p.R396Q | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs904186727, COSV55404690; called by muse, mutect2, varscan2
- SDK2 | c.3515G>A p.R1172H | Missense Mutation (SNP) | VAF 78/455 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as rs145582973; called by muse, mutect2, varscan2
- SHISA3 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 76/362 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs761118083, COSV59979508; called by muse, mutect2, varscan2
- TTN | c.390C>G p.I130M | Missense Mutation (SNP) | VAF 17/72 reads (24%) | PolyPhen probably damaging (0.994); catalogued as COSV100594758; called by muse, mutect2, varscan2
- VPS16 | c.1206C>T p.A402= | Splice Region (SNP) | VAF 76/498 reads (15%) | catalogued as rs1225443675, COSV66793153; called by muse, mutect2, varscan2
- ZFR2 | c.2618G>A p.R873Q | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as rs770396423, COSV53600657; called by muse, mutect2, varscan2
- ZNF710 | c.1657G>A p.G553R | Missense Mutation (SNP) | VAF 17/169 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1315758279, COSV51566332; called by muse, mutect2, varscan2
- ZNF829 | c.367C>T p.H123Y | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.94); PolyPhen benign (0.012); catalogued as rs1354336301; called by muse, mutect2, varscan2
- CLEC7A | c.43T>C p.Y15H | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DEPDC5 | c.1287+1G>A p.X429_splice | Splice Site (SNP) | VAF 18/89 reads (20%) | called by muse, mutect2, varscan2
- GLDC | c.1851-6T>A | Splice Region (SNP) | VAF 24/514 reads (5%) | called by muse, mutect2
- HDAC2 | c.1392A>C p.E464D | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- HDAC8 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 43/225 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- IER3 | c.376T>A p.S126T | Missense Mutation (SNP) | VAF 67/335 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- METTL2B | c.686A>G p.D229G | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- PER1 | c.1234+5G>A | Splice Region (SNP) | VAF 13/355 reads (4%) | called by muse, mutect2
- PHKG2 | c.1207C>T p.L403F | Missense Mutation (SNP) | VAF 18/322 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.023); called by muse, mutect2
- SRPRB | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TGM6 | c.1531C>A p.L511M | Missense Mutation (SNP) | VAF 89/518 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- TGS1 | c.1623C>G p.H541Q | Missense Mutation (SNP) | VAF 41/179 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- WASF1 | c.1234G>T p.V412F | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- WASHC2C | c.3190G>C p.G1064R (on ENST00000336378; = p.G1043R on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/718 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.028); called by muse, mutect2
- WWOX | c.591C>A p.F197L | Missense Mutation (SNP) | VAF 50/272 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- ZIC3 | c.401G>A p.G134D | Missense Mutation (SNP) | VAF 47/206 reads (23%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
- ZNF862 | c.1048C>G p.L350V | Missense Mutation (SNP) | VAF 64/349 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- ACOX2 | c.1395G>A p.T465= | Silent (SNP) | VAF 26/182 reads (14%) | catalogued as rs1361574689; called by muse, mutect2, varscan2
- CD163L1 | c.1065C>T p.N355= | Silent (SNP) | VAF 47/247 reads (19%) | catalogued as rs369551730; called by muse, mutect2, varscan2
- CNTNAP2 | c.18C>T p.R6= | Silent (SNP) | VAF 36/283 reads (13%) | catalogued as COSV62265327; called by muse, mutect2, varscan2
- EPHB1 | c.915C>T p.T305= | Silent (SNP) | VAF 46/261 reads (18%) | catalogued as rs371516686; called by muse, mutect2, varscan2
- FRRS1 | c.156C>T p.Y52= | Silent (SNP) | VAF 38/175 reads (22%) | catalogued as rs756818505; called by muse, mutect2, varscan2
- MAGEE1 | c.669C>T p.S223= | Silent (SNP) | VAF 59/414 reads (14%) | catalogued as COSV100819393; called by muse, mutect2, varscan2
- NCR1 | c.504C>T p.Y168= | Silent (SNP) | VAF 75/354 reads (21%) | catalogued as rs765774550, COSV52555417, COSV52555583; called by muse, mutect2, varscan2
- NEFM | c.2484C>T p.G828= | Silent (SNP) | VAF 84/322 reads (26%) | catalogued as rs555106103; called by muse, mutect2, varscan2
- NOD2 | c.126C>G p.V42= | Silent (SNP) | VAF 62/142 reads (44%) | called by muse, mutect2, varscan2
- PLAT | c.525C>T p.N175= | Silent (SNP) | VAF 24/84 reads (29%) | catalogued as rs1326934341; called by muse, mutect2
- PTPDC1 | c.192G>A p.K64= (on ENST00000375360 / NM_177995.3; = p.K116= on NM_152422.4) | Silent (SNP) | VAF 47/222 reads (21%) | called by muse, mutect2, varscan2
- SOX17 | c.513C>T p.G171= | Silent (SNP) | VAF 52/229 reads (23%) | catalogued as rs766423684; called by muse, mutect2, varscan2
- STAMBP | c.192C>T p.N64= | Silent (SNP) | VAF 45/219 reads (21%) | called by muse, mutect2, varscan2
- TCHH | c.4017C>T p.R1339= | Silent (SNP) | VAF 58/251 reads (23%) | called by muse, mutect2, varscan2
- YAP1 | c.852C>T p.P284= (on ENST00000282441 / NM_001130145.3; = p.P246= on NM_006106.5) | Silent (SNP) | VAF 9/126 reads (7%) | called by muse, mutect2
- ZDHHC20 | c.51G>A p.V17= | Silent (SNP) | VAF 25/152 reads (16%) | called by muse, mutect2, varscan2
- ABCA4 | c.6282+225C>T | Intron (SNP) | VAF 46/277 reads (17%) | catalogued as rs1389779112; called by muse, mutect2, varscan2
- AL021937.5 | n.22C>A | RNA (SNP) | VAF 12/70 reads (17%) | called by muse, mutect2, varscan2
- AL645922.1 | c.-11G>C | 5'UTR (SNP) | VAF 16/352 reads (5%) | catalogued as rs1377899237; called by muse, mutect2
- ANXA2P2 | n.104C>A | RNA (SNP) | VAF 47/273 reads (17%) | called by muse, mutect2, varscan2
- C10orf143 | c.69+2755G>T | Intron (SNP) | VAF 20/324 reads (6%) | called by muse, mutect2
- DST | c.4297-4588G>A | Intron (SNP) | VAF 24/206 reads (12%) | catalogued as rs370912424; ClinVar: likely benign; called by muse, mutect2, varscan2
- FAM20A | c.*1076del | 3'UTR (DEL) | VAF 34/216 reads (16%) | catalogued as rs1568713203; called by mutect2, pindel, varscan2
- MIR143 | n.89G>A | RNA (SNP) | VAF 20/127 reads (16%) | called by muse, mutect2, varscan2
- PHYH | c.246-19T>G | Intron (SNP) | VAF 39/156 reads (25%) | called by muse, mutect2, varscan2
- PSG3 | c.*6G>A | 3'UTR (SNP) | VAF 30/140 reads (21%) | catalogued as rs761028412; called by muse, mutect2, varscan2
- SLC6A3 | c.-1C>G | 5'UTR (SNP) | VAF 18/292 reads (6%) | called by muse, mutect2
- SLIT3 | c.198-12203C>A | Intron (SNP) | VAF 29/85 reads (34%) | called by muse, mutect2, varscan2
- SNRNP40 | c.-36C>G | 5'UTR (SNP) | VAF 13/71 reads (18%) | catalogued as rs775006466; called by muse, varscan2
